Somatic mutation profile of tumor specimen 0DSI9F from CCDI case PBCHRZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.4 years (2,721 days).
Specimen 0DSI9F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a29f273-0d03-4ec7-9630-59871b05a9f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSI82 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3efe33f2-f6bf-47eb-8894-06e63592f6d4

The open-access MAF lists 23 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 4, 3'UTR 1, RNA 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAIAP3 | c.1480C>G p.P494A | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs764466148; called by muse, mutect2, varscan2
- CPNE8 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 154/703 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100503625, COSV58849153; called by muse, mutect2, varscan2
- MAEL | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 329/666 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV63112291; called by muse, mutect2, varscan2
- SNRPA | c.454C>A p.R152S | Missense Mutation (SNP) | VAF 102/525 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.139); catalogued as COSV54681006, COSV99698857; called by muse, mutect2, varscan2
- WDR97 | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 104/364 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV59363573; called by muse, mutect2, varscan2
- ZNF676 | c.129G>C p.L43= (on ENST00000650058; = p.L11= on NM_001001411.3) | Splice Region (SNP) | VAF 15/474 reads (3%) | catalogued as COSV68094847; called by muse, mutect2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 33/1066 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- CFAP61 | c.2424C>A p.C808* | Nonsense Mutation (SNP) | VAF 89/883 reads (10%) | called by muse, mutect2, varscan2
- GLOD4 | c.263A>G p.Y88C (on ENST00000301328 / NM_001366247.1; = p.Y73C on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/480 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBSCN | c.10838A>G p.E3613G | Missense Mutation (SNP) | VAF 71/353 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SGO2 | c.2924A>G p.Q975R | Missense Mutation (SNP) | VAF 76/1022 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2
- YTHDC1 | c.559A>G p.S187G | Missense Mutation (SNP) | VAF 128/1254 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BPIFB3 | c.1266G>A p.S422= | Silent (SNP) | VAF 41/466 reads (9%) | catalogued as rs777904958, COSV64957631; called by muse, mutect2
- DDN | c.1872T>G p.P624= | Silent (SNP) | VAF 68/748 reads (9%) | called by muse, mutect2
- DDO | c.414C>T p.T138= | Silent (SNP) | VAF 84/582 reads (14%) | catalogued as COSV100927899; called by muse, mutect2, varscan2
- NUDT22 | c.504C>T p.P168= | Silent (SNP) | VAF 294/318 reads (92%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 41/1245 reads (3%) | called by muse, mutect2
- FLII | c.175-59G>A | Intron (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- MMADHC | c.*25A>G | 3'UTR (SNP) | VAF 75/339 reads (22%) | called by muse, mutect2, varscan2
- MYO19 | c.1231+61A>G | Intron (SNP) | VAF 14/285 reads (5%) | called by muse, mutect2
- RPL23AP94 | n.259C>A | RNA (SNP) | VAF 69/573 reads (12%) | called by muse, mutect2, varscan2
- SEC14L4 | c.1081+75C>T | Intron (SNP) | VAF 17/276 reads (6%) | catalogued as rs957321243; called by muse, mutect2
- SLC3A2 | c.1303-29G>A | Intron (SNP) | VAF 123/162 reads (76%) | called by muse, mutect2, varscan2
